Somatic mutation profile of tumor specimen f4034d75-d533-47c2-8453-068e37 (aliquot f4034d75-d533-47c2-8453-068e37_D6) from CPTAC case 17OV040, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen f4034d75-d533-47c2-8453-068e37: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19507ae0-0261-4ced-998b-b1330ed39641.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen e0fd3f72-2df3-4696-9114-a5b31b (Blood Derived Normal), aliquot e0fd3f72-2df3-4696-9114-a5b31b_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e40eb6cd-7912-4ce2-b413-61b02b7009a8

The open-access MAF lists 33 somatic variants for this specimen: 29 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 2, Intron 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 47/351 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL4A1 | c.1826G>T p.G609V | Missense Mutation (SNP) | VAF 38/451 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65420810; called by muse, mutect2
- CYTH2 | c.835C>T p.R279W (on ENST00000427476; = p.R278W on NM_004228.7) | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1188088624; called by muse, mutect2, varscan2
- EPPK1 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 28/317 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs782220071, COSV73262266; called by muse, mutect2
- ESPNL | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 54/365 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs778024556, COSV54541083; called by muse, mutect2, varscan2
- HNF1B | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 91/507 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as CM055550; called by muse, mutect2, varscan2
- NDUFS2 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 46/487 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs375650413, COSV100917549; ClinVar: likely benign; called by muse, mutect2
- PROS1 | c.1030A>G p.I344V | Missense Mutation (SNP) | VAF 56/334 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.026); catalogued as rs773309134; called by muse, mutect2, varscan2
- TOX3 | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 80/545 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.271); catalogued as rs751494331, COSV54863225; called by muse, mutect2, varscan2
- UAP1 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs750635643; called by muse, mutect2
- UNC13C | c.3169C>T p.R1057W | Missense Mutation (SNP) | VAF 34/306 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs777356905, COSV52890344; called by muse, mutect2, varscan2
- DISP3 | c.3115T>C p.Y1039H | Missense Mutation (SNP) | VAF 39/311 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- DPYD | c.2029G>C p.E677Q | Missense Mutation (SNP) | VAF 40/467 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HMBOX1 | c.215A>T p.Y72F | Missense Mutation (SNP) | VAF 20/684 reads (3%) | SIFT tolerated (0.69); PolyPhen benign (0.222); called by muse, mutect2
- IL9R | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 67/570 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KANK4 | c.1094A>G p.Q365R | Missense Mutation (SNP) | VAF 65/405 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LHX8 | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 44/330 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- MID1 | c.317T>C p.F106S | Missense Mutation (SNP) | VAF 13/326 reads (4%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2
- MRTFB | c.971C>A p.S324Y | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- PRKDC | c.4875C>G p.H1625Q | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.041); called by muse, mutect2
- RNF139 | c.1895A>T p.D632V | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2
- SLC12A1 | c.1163dup p.A390Sfs*58 | Frame Shift Ins (INS) | VAF 38/254 reads (15%) | called by mutect2, varscan2
- SLC44A5 | c.1861G>C p.A621P | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); called by muse, mutect2
- SOWAHA | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- ST7L | c.1269A>C p.L423F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TBC1D7 | c.268C>G p.H90D | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.151); called by muse, mutect2
- TUBA3D | c.855G>C p.Q285H | Missense Mutation (SNP) | VAF 77/524 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- ZBTB17 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 28/440 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.147); called by muse, mutect2
- ZNF354A | c.160+2T>A p.X54_splice | Splice Site (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- MXRA8 | c.897C>A p.P299= | Silent (SNP) | VAF 58/378 reads (15%) | called by muse, mutect2, varscan2
- ZNF735 | c.699A>G p.R233= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as rs756518675; called by muse, mutect2, varscan2
- DLG2 | c.1510+61819T>C | Intron (SNP) | VAF 20/134 reads (15%) | called by muse, mutect2, varscan2
- Z82195.2 | n.416-19553C>T | Intron (SNP) | VAF 26/269 reads (10%) | catalogued as rs921166448; called by muse, mutect2
